Somatic mutation profile of tumor specimen 0DGUTA from CCDI case PBBTTN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.9 years (1,793 days).
Specimen 0DGUTA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ded3f72-a609-4dbe-8d39-d6b6af85ec76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGUS9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9347f98-c741-4b87-b84d-da1ddd72e330

The open-access MAF lists 9,227 somatic variants for this specimen: 5,492 protein-altering or splice-affecting, 1,820 silent, 1,915 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,636, Silent 1,820, Intron 1,108, 3'UTR 419, Nonsense Mutation 359, Splice Site 263, 5'UTR 249, Splice Region 122, Frame Shift Ins 60, RNA 57, 5'Flank 45, Frame Shift Del 43.

Variants (750 of 9,227; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD3G | c.213dup p.W72Mfs*6 | Frame Shift Ins (INS) | VAF 278/740 reads (38%) | catalogued as rs570768621; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CFTR | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 285/704 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397508718, CM086804, CM950239, COSV50079373; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFTR | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 313/796 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs397508764, CM024663; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A2 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 66/577 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs387906610, CM099128, COSV52430808; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.5701-1G>T p.X1901_splice | Splice Site (SNP) | VAF 341/742 reads (46%) | catalogued as rs1553855868, CS151977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 456/1082 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- FLG | c.4420C>T p.R1474* | Nonsense Mutation (SNP) | VAF 150/380 reads (39%) | catalogued as rs146686141, CM071764; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HEXA | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 297/713 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28941770, CM880041, CM910216; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 375/931 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473662, CM057173, COSV50121965; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- LMNA | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 340/862 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs753988867; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- OTOGL | c.5449C>T p.R1817* (on ENST00000547103; = p.R1808* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 215/794 reads (27%) | catalogued as rs768620276, CM134337, COSV54024520; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLD1 | c.1433G>A p.S478N | Missense Mutation (SNP) | VAF 299/739 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs397514632, CM1212503, COSV70955559; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPM1D | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 127/307 reads (41%) | catalogued as rs1064797099, CM124484, COSV59954253; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRIP4 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 151/460 reads (33%) | catalogued as rs869312827, CM162647, COSV56030281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.5056C>T p.Q1686* | Nonsense Mutation (SNP) | VAF 350/917 reads (38%) | catalogued as rs45517388, CM052387; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 256/630 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV50963018; called by muse, mutect2, varscan2
- AARS1 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 291/751 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751300562; called by muse, mutect2, varscan2
- AARS1 | c.571C>A p.H191N | Missense Mutation (SNP) | VAF 238/584 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479571939; called by muse, varscan2
- AASS | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 272/690 reads (39%) | catalogued as COSV62789449; called by muse, mutect2, varscan2
- ABCA10 | c.2579G>A p.G860D | Missense Mutation (SNP) | VAF 338/844 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs929996015; called by muse, varscan2
- ABCA13 | c.9313C>A p.H3105N | Missense Mutation (SNP) | VAF 266/706 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV101446961; called by muse, mutect2, varscan2
- ABCA3 | c.4094G>T p.R1365M | Missense Mutation (SNP) | VAF 378/884 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57054128; called by muse, mutect2, varscan2
- ABCA5 | c.200A>T p.N67I | Missense Mutation (SNP) | VAF 168/606 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV67018525; called by muse, mutect2, varscan2
- ABCA7 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 275/661 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs138055574, COSV54038939; called by muse, mutect2, varscan2
- ABCA7 | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 335/822 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs999060047; called by muse, mutect2, varscan2
- ABCA9 | c.2767G>A p.G923R | Missense Mutation (SNP) | VAF 217/508 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs146820712; called by muse, mutect2, varscan2
- ABCB5 | c.2154C>T p.T718= (on ENST00000404938 / NM_001163941.2; = p.T273= on NM_178559.6) | Splice Region (SNP) | VAF 54/588 reads (9%) | catalogued as rs1376608891; called by muse, mutect2
- ABCC11 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 251/652 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1428811478; called by muse, mutect2, varscan2
- ABCC5 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 494/1115 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs778058381, COSV99656829; called by muse, mutect2, varscan2
- ABCD4 | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 369/938 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100084432; called by muse, mutect2, varscan2
- ABCD4 | c.1154C>T p.T385I | Missense Mutation (SNP) | VAF 316/819 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1384266007; called by muse, mutect2, varscan2
- ABCG4 | c.1364G>T p.R455M | Missense Mutation (SNP) | VAF 271/662 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56644931; called by muse, mutect2, varscan2
- ABHD12 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 291/722 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771678284; called by muse, mutect2, varscan2
- ABLIM3 | c.889-2A>G p.X297_splice | Splice Site (SNP) | VAF 294/683 reads (43%) | catalogued as rs974757442; called by muse, mutect2, varscan2
- ABO | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 383/1008 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1259797239, COSV101506007; called by muse, mutect2, varscan2
- AC093512.2 | c.*889-1G>T | Splice Site (SNP) | VAF 52/836 reads (6%) | catalogued as COSV57633852; called by muse, mutect2
- AC144573.1 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 196/642 reads (31%) | SIFT deleterious, low confidence (0); catalogued as COSV100294272; called by muse, mutect2, varscan2
- ACAD10 | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 284/702 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764914739; called by muse, mutect2, varscan2
- ACAN | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 289/706 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs144835580, COSV61360708; called by muse, mutect2, varscan2
- ACO2 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 520/1186 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.152); catalogued as rs777890868; called by muse, mutect2, varscan2
- ACOT4 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100412812; called by muse, mutect2
- ACR | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs765965924; called by muse, varscan2
- ACSBG2 | c.1156C>A p.L386I | Missense Mutation (SNP) | VAF 138/354 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV53123619, COSV53123781; called by muse, varscan2
- ACSS3 | c.1358C>A p.T453N | Missense Mutation (SNP) | VAF 179/410 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs768448971; called by muse, mutect2, varscan2
- ACTL9 | c.168G>T p.M56I | Missense Mutation (SNP) | VAF 162/344 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100185259; called by muse, mutect2
- ACTN1 | c.1234+1G>A p.X412_splice | Splice Site (SNP) | VAF 377/878 reads (43%) | catalogued as rs776298946; called by muse, mutect2, varscan2
- ACTN3 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 288/741 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs999104173, COSV72207534; called by muse, mutect2, varscan2
- ACTN4 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 492/1162 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1031037100, COSV53142731; called by muse, mutect2, varscan2
- ADAMTS12 | c.4067C>A p.P1356H | Missense Mutation (SNP) | VAF 289/733 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as COSV100710286; called by muse, mutect2, varscan2
- ADAMTS20 | c.4168G>T p.G1390C | Missense Mutation (SNP) | VAF 330/1083 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67132660; called by muse, mutect2, varscan2
- ADAMTS4 | c.1846C>T p.Q616* | Nonsense Mutation (SNP) | VAF 284/614 reads (46%) | catalogued as rs142227379; called by muse, mutect2
- ADAMTS6 | c.2702C>T p.P901L | Missense Mutation (SNP) | VAF 48/1282 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV58681998; called by muse, mutect2
- ADARB2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 210/501 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.241); catalogued as COSV67215727, COSV67217948; called by muse, mutect2, varscan2
- ADCK5 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 86/1312 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs958511109, COSV58232644; called by muse, mutect2
- ADCY3 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 289/616 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs760416852, COSV53170376; called by muse, mutect2, varscan2
- ADCY6 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 232/480 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs766206185, COSV57166573; called by muse, mutect2, varscan2
- ADCY8 | c.1356G>A p.E452= | Splice Region (SNP) | VAF 48/1024 reads (5%) | catalogued as rs1241106420; called by muse, mutect2
- ADGRB1 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 211/466 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs549410622; called by muse, mutect2, varscan2
- ADGRB1 | c.4255C>T p.P1419S | Missense Mutation (SNP) | VAF 223/654 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs1304499081; called by muse, mutect2, varscan2
- ADGRB3 | c.3555G>T p.M1185I | Missense Mutation (SNP) | VAF 248/635 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV53243570; called by muse, varscan2
- ADGRF2 | c.588T>A p.C196* (on ENST00000296862 / NM_001368115.2; = p.C128* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 342/702 reads (49%) | catalogued as COSV99731140; called by muse, varscan2
- ADGRG4 | c.3865C>T p.R1289W | Missense Mutation (SNP) | VAF 304/338 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs370436636; called by muse, varscan2
- ADGRG5 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 212/510 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs759036606; called by muse, varscan2
- ADGRL3 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 461/1137 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV72268835; called by muse, mutect2, varscan2
- ADH1A | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 237/520 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1241562908; called by muse, mutect2, varscan2
- ADH6 | c.664G>T p.G222* | Nonsense Mutation (SNP) | VAF 445/1094 reads (41%) | catalogued as COSV52957332; called by muse, mutect2, varscan2
- ADORA1 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 386/936 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1231550931, COSV55142901; called by muse, varscan2
- ADORA2B | c.806A>G p.K269R | Missense Mutation (SNP) | VAF 341/811 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.326); catalogued as rs748666257, COSV58482840; called by muse, varscan2
- ADRB1 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 368/818 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65168324; called by muse, mutect2, varscan2
- AEBP1 | c.535C>A p.L179M | Missense Mutation (SNP) | VAF 399/989 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.365); catalogued as COSV56258358; called by muse, mutect2, varscan2
- AEBP1 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 370/939 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV104384702; called by muse, mutect2, varscan2
- AEBP2 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 174/517 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV56862844, COSV56863268; called by muse, varscan2
- AGAP3 | c.1495G>A p.V499I (on ENST00000622464; = p.V535I on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 483/1198 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs757721635, COSV68247083; called by muse, mutect2, varscan2
- AGBL1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 245/646 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs763367858; called by muse, mutect2, varscan2
- AGBL5 | c.643G>T p.G215W | Missense Mutation (SNP) | VAF 368/913 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59937376; called by muse, mutect2, varscan2
- AGGF1 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 237/663 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as rs751751543; called by muse, mutect2, varscan2
- AGPAT4 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 452/1056 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756140825, COSV57248889; called by mutect2, varscan2
- AHCTF1 | c.6311C>T p.T2104I (on ENST00000366508; = p.T2078I on NM_015446.5) | Missense Mutation (SNP) | VAF 434/1125 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1471768463; called by muse, mutect2, varscan2
- AHSG | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 259/647 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV56606944; called by muse, mutect2, varscan2
- AK5 | c.983-1G>T p.X328_splice (on ENST00000354567 / NM_174858.3; = p.X302_splice on NM_012093.4) | Splice Site (SNP) | VAF 295/722 reads (41%) | catalogued as COSV60969733; called by muse, mutect2, varscan2
- AKAP11 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 324/820 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs757090321, COSV50299408; called by muse, mutect2, varscan2
- AKAP13 | c.7670C>T p.A2557V (on ENST00000394518 / NM_007200.5; = p.A2561V on NM_006738.6) | Missense Mutation (SNP) | VAF 175/1001 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1236425337; called by muse, mutect2
- AKAP4 | c.465C>A p.C155* | Nonsense Mutation (SNP) | VAF 322/377 reads (85%) | catalogued as rs1557204131, COSV62074958; called by muse, mutect2, varscan2
- AKAP7 | c.830G>A p.C277Y | Missense Mutation (SNP) | VAF 265/681 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53838014; called by muse, mutect2, varscan2
- AKNA | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 455/1011 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs1435155418; called by muse, mutect2, varscan2
- AKNAD1 | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 66/621 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV100645811; called by muse, mutect2, varscan2
- AKT1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 414/984 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs375990114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL645922.1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 251/622 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.083); catalogued as COSV100191166, COSV54960036; called by muse, mutect2, varscan2
- ALDH16A1 | c.1906del p.A636Pfs*12 | Frame Shift Del (DEL) | VAF 254/620 reads (41%) | catalogued as rs1462501220; called by mutect2, varscan2
- ALDH18A1 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 372/918 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs373404824, COSV64662150; called by muse, varscan2
- ALDH6A1 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 260/653 reads (40%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.447); catalogued as COSV63246799; called by muse, varscan2
- ALDOB | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 293/780 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.404); catalogued as rs1241120665; called by muse, mutect2, varscan2
- ALG8 | c.1374G>A p.W458* | Nonsense Mutation (SNP) | VAF 358/840 reads (43%) | catalogued as rs1272213807; called by muse, varscan2
- ALKBH5 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 436/1018 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.212); catalogued as rs751699434, COSV67686932; called by muse, mutect2, varscan2
- ALPK2 | c.5572T>C p.C1858R | Missense Mutation (SNP) | VAF 235/615 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277437566; called by muse, mutect2, varscan2
- ALPK3 | c.4705C>A p.L1569I | Missense Mutation (SNP) | VAF 251/658 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360177; called by muse, mutect2, varscan2
- ALS2 | c.3893A>G p.D1298G | Missense Mutation (SNP) | VAF 46/1092 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1046967010; called by muse, mutect2
- ALS2 | c.-60G>A | Splice Region (SNP) | VAF 278/742 reads (37%) | catalogued as rs1381259990; called by muse, varscan2
- AMH | c.1402A>G p.S468G | Missense Mutation (SNP) | VAF 308/702 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV99039789; called by muse, mutect2, varscan2
- AMHR2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 292/695 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs553240253, COSV99143258; called by muse, mutect2, varscan2
- AMIGO2 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 244/540 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99873843; called by muse, mutect2, varscan2
- AMPD2 | c.112del p.A38Pfs*95 | Frame Shift Del (DEL) | VAF 232/544 reads (43%) | catalogued as rs1403470706; called by mutect2, varscan2
- ANAPC2 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 341/834 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.818); catalogued as rs867348084; called by muse, mutect2, varscan2
- ANAPC7 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 244/596 reads (41%) | catalogued as COSV71443853; called by muse, mutect2, varscan2
- ANK3 | c.10760C>T p.T3587M | Missense Mutation (SNP) | VAF 296/792 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1311916565, COSV55060547; called by muse, mutect2, varscan2
- ANK3 | c.9457C>A p.L3153I | Missense Mutation (SNP) | VAF 189/486 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99780031; called by muse, mutect2, varscan2
- ANKAR | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 65/577 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs1231161049; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7654C>T p.P2552S | Missense Mutation (SNP) | VAF 248/702 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs1039334672; called by muse, mutect2, varscan2
- ANKRD18B | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 89/1236 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV99340711; called by muse, mutect2
- ANKRD20A2P | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 64/573 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs1488545103; called by muse, mutect2, varscan2
- ANKS4B | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 282/691 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs561061456; called by muse, mutect2, varscan2
- ANO1 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 146/417 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as rs1411622165; called by muse, mutect2, varscan2
- ANO3 | c.2308G>T p.A770S | Missense Mutation (SNP) | VAF 302/795 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56802360; called by muse, mutect2, varscan2
- ANP32D | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 60/562 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as rs890426022; called by muse, varscan2
- AOX1 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 277/660 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV65983300; called by muse, mutect2, varscan2
- AP3D1 | c.1703T>C p.V568A | Missense Mutation (SNP) | VAF 486/1022 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.874); catalogued as rs561795998; called by muse, mutect2, varscan2
- APC2 | c.4874C>T p.A1625V | Missense Mutation (SNP) | VAF 291/677 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs1321678250; called by muse, mutect2, varscan2
- APOE | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.108); catalogued as rs770942678; called by muse, mutect2, varscan2
- ARC | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 108/243 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.14); catalogued as rs1403566740; called by muse, mutect2, varscan2
- ARFGEF1 | c.2527-1G>A p.X843_splice | Splice Site (SNP) | VAF 112/303 reads (37%) | catalogued as COSV51606951; called by muse, varscan2
- ARFGEF1 | c.1922-1G>T p.X641_splice | Splice Site (SNP) | VAF 181/404 reads (45%) | catalogued as COSV99141411; called by muse, mutect2, varscan2
- ARFGEF1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 281/671 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764719716, COSV51607682; called by muse, mutect2, varscan2
- ARG1 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 409/1005 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as COSV51581604; called by muse, mutect2, varscan2
- ARHGAP18 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 202/590 reads (34%) | catalogued as rs1364770988; called by muse, mutect2, varscan2
- ARHGAP20 | c.1873C>A p.L625I | Missense Mutation (SNP) | VAF 218/608 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1046774323; called by mutect2, varscan2
- ARHGAP21 | c.4329G>T p.K1443N | Missense Mutation (SNP) | VAF 399/1053 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV100255754, COSV100256203; called by muse, mutect2, varscan2
- ARHGAP22 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 173/451 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as rs1158727629; called by muse, mutect2, varscan2
- ARHGAP30 | c.1943G>A p.G648D | Missense Mutation (SNP) | VAF 304/771 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs772339887; called by muse, mutect2, varscan2
- ARHGAP36 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 336/445 reads (76%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1347804086; called by muse, mutect2, varscan2
- ARHGAP39 | c.2066C>T p.S689F | Missense Mutation (SNP) | VAF 474/1072 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs756869100; called by muse, mutect2, varscan2
- ARHGAP5 | c.3133G>A p.V1045I | Missense Mutation (SNP) | VAF 238/574 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs374565403; called by muse, mutect2, varscan2
- ARID3A | c.570G>T p.R190S | Missense Mutation (SNP) | VAF 364/907 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1483911661; called by muse, mutect2, varscan2
- ARID5B | c.3451G>T p.G1151* | Nonsense Mutation (SNP) | VAF 261/586 reads (45%) | catalogued as COSV54433727; called by muse, mutect2, varscan2
- ARL14EP | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 373/895 reads (42%) | catalogued as COSV99956126; called by muse, mutect2, varscan2
- ARMC10 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 61/1433 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774834954; called by muse, mutect2
- ARMC4 | c.2140G>A p.G714R | Missense Mutation (SNP) | VAF 267/729 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs866425433; called by muse, mutect2, varscan2
- ARMC6 | c.34G>T p.G12* | Nonsense Mutation (SNP) | VAF 200/517 reads (39%) | catalogued as COSV54182618; called by muse, mutect2, varscan2
- ARMCX5 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 331/375 reads (88%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs761752157; called by muse, mutect2, varscan2
- ARNT2 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 250/518 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV100308957; called by muse, mutect2, varscan2
- ARPP21 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 236/604 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51806536; called by muse, mutect2, varscan2
- ASB6 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 380/869 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99475583; called by muse, mutect2, varscan2
- ASCC1 | c.583G>A p.V195I (on ENST00000342444 / NM_001369085.1; = p.V167I on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 314/799 reads (39%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.487); catalogued as rs765393079, COSV57725259; called by muse, mutect2, varscan2
- ASCL2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 275/649 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV58713437; called by muse, mutect2, varscan2
- ASIC2 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 136/283 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs147403420; called by muse, mutect2, varscan2
- ASL | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 258/628 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs796051925, CM141230; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPHD2 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 216/609 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.908); catalogued as rs759302880; called by muse, mutect2, varscan2
- ASXL2 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 287/761 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55466731; called by muse, mutect2, varscan2
- ASZ1 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 296/766 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as rs762171269, COSV52915232; called by mutect2, varscan2
- ATAD2 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 100/1335 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.982); catalogued as rs1233186995; called by muse, mutect2
- ATF1 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 194/538 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1010348375; called by muse, varscan2
- ATG10 | c.170C>A p.S57* | Nonsense Mutation (SNP) | VAF 235/618 reads (38%) | catalogued as COSV56422416; called by muse, mutect2, varscan2
- ATG2A | c.5209C>T p.R1737C | Missense Mutation (SNP) | VAF 228/560 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1471217439; called by muse, mutect2, varscan2
- ATM | c.663-1G>T p.X221_splice | Splice Site (SNP) | VAF 97/213 reads (46%) | catalogued as COSV53727391, COSV53752081; called by muse, mutect2, varscan2
- ATM | c.2680G>T p.D894Y | Missense Mutation (SNP) | VAF 338/845 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as CD137679; called by muse, mutect2, varscan2
- ATM | c.5002C>A p.L1668I | Missense Mutation (SNP) | VAF 281/720 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.458); catalogued as rs747317946; ClinVar: uncertain significance; called by muse, varscan2
- ATP11A | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 329/796 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99370287; called by muse, mutect2, varscan2
- ATP13A5 | c.2434T>G p.L812V | Missense Mutation (SNP) | VAF 241/578 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV60872447; called by muse, varscan2
- ATP2B1 | c.2756G>A p.R919K | Missense Mutation (SNP) | VAF 74/729 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs940976725, COSV53806748; called by muse, mutect2
- ATP2B3 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 466/508 reads (92%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs200641356, COSV54848455; called by muse, mutect2, varscan2
- ATP2B4 | c.3430C>T p.R1144* | Nonsense Mutation (SNP) | VAF 268/686 reads (39%) | catalogued as rs1343909167; called by muse, mutect2, varscan2
- ATP5PB | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 247/671 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); catalogued as COSV71953323; called by muse, mutect2, varscan2
- ATP8A2 | c.1777G>T p.G593W | Missense Mutation (SNP) | VAF 60/1096 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54976847; called by muse, mutect2
- ATP8B1 | c.839T>C p.F280S | Missense Mutation (SNP) | VAF 252/650 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1555692584; ClinVar: uncertain significance; called by muse, varscan2
- ATP8B4 | c.2609G>A p.C870Y | Missense Mutation (SNP) | VAF 344/874 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144607474; called by muse, mutect2, varscan2
- ATP9A | c.894G>T p.L298F | Missense Mutation (SNP) | VAF 276/699 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV100125339; called by muse, mutect2, varscan2
- ATXN1 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 385/995 reads (39%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as rs867802797, COSV55208689; called by muse, mutect2, varscan2
- AVEN | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 64/682 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV60733340, COSV60737584; called by muse, mutect2
- AVL9 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 54/1410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59468097; called by muse, mutect2
- B4GALT4 | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 158/409 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV100785800; called by muse, mutect2, varscan2
- BCAN | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 145/274 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV100227934; called by muse, mutect2, varscan2
- BCL11A | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 322/816 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1291712052; called by muse, mutect2, varscan2
- BCL2L13 | c.1236G>T p.K412N | Missense Mutation (SNP) | VAF 230/897 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as COSV58225937; called by muse, mutect2, varscan2
- BCL9 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 214/514 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs1553204515, COSV52345206; called by muse, mutect2, varscan2
- BCLAF1 | c.1788G>T p.Q596H | Missense Mutation (SNP) | VAF 370/1038 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs764728018, COSV100786553; called by muse, mutect2, varscan2
- BCOR | c.3217G>T p.E1073* | Nonsense Mutation (SNP) | VAF 284/322 reads (88%) | catalogued as COSV60698999; called by muse, mutect2, varscan2
- BEND3 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 289/628 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs377099257; called by muse, mutect2, varscan2
- BEND3 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 306/831 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs782148186; called by muse, mutect2, varscan2
- BEST2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 275/863 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs571724788; called by muse, mutect2, varscan2
- BLVRB | c.244A>G p.S82G | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1369740621; called by muse, mutect2, varscan2
- BMP4 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 38/930 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.756); catalogued as COSV99816930; called by muse, mutect2
- BMPER | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 121/1938 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1052945471; called by muse, mutect2
- BOD1L1 | c.2939C>T p.S980L | Missense Mutation (SNP) | VAF 401/953 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV50007692; called by muse, mutect2, varscan2
- BOP1 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 442/1044 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs781951059, COSV56639299; called by muse, mutect2, varscan2
- BPTF | c.5344G>A p.V1782M | Missense Mutation (SNP) | VAF 83/769 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as rs773572080; called by muse, mutect2, varscan2
- BRAT1 | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 95/834 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs749500692; called by muse, mutect2, varscan2
- BRAT1 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 402/872 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as rs1446689584, COSV61396389; called by muse, mutect2, varscan2
- BRCA1 | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 319/821 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV58799672; called by muse, mutect2
- BRCA2 | c.1481T>C p.V494A | Missense Mutation (SNP) | VAF 288/718 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as rs786202205, COSV66454271; ClinVar: uncertain significance; called by muse, varscan2
- BRCA2 | c.6241G>T p.E2081* | Nonsense Mutation (SNP) | VAF 338/860 reads (39%) | catalogued as COSV66458236; called by muse, mutect2, varscan2
- BRF2 | c.1022A>T p.N341I | Missense Mutation (SNP) | VAF 250/602 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs774175187; called by muse, mutect2, varscan2
- BRPF3 | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 372/908 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1229758606; called by muse, varscan2
- BTG4 | c.347C>A p.S116Y | Missense Mutation (SNP) | VAF 189/566 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.793); catalogued as rs1057118464; called by muse, mutect2, varscan2
- BTN2A1 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 379/978 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57003376; called by muse, mutect2, varscan2
- C10orf53 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 277/776 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934854; called by muse, mutect2, varscan2
- C11orf21 | c.310C>T p.R104W (on ENST00000381153 / NM_001329958.2; = p.R150W on NM_001142946.3) | Missense Mutation (SNP) | VAF 339/864 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs762777190; called by muse, mutect2, varscan2
- C12orf50 | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 305/728 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775620385; called by muse, mutect2, varscan2
- C12orf66 | c.237G>A p.G79= | Splice Region (SNP) | VAF 399/894 reads (45%) | catalogued as rs764041929; called by muse, mutect2, varscan2
- C16orf78 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 382/983 reads (39%) | catalogued as COSV100147717; called by muse, varscan2
- C16orf96 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 303/673 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as rs968329437; called by muse, mutect2, varscan2
- C1orf158 | c.527G>A p.W176* | Nonsense Mutation (SNP) | VAF 248/565 reads (44%) | catalogued as rs746423757; called by muse, mutect2, varscan2
- C1orf54 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 208/553 reads (38%) | catalogued as rs1553853105, COSV51744254; called by muse, mutect2, varscan2
- C2CD5 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 507/1187 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61724961; called by muse, mutect2, varscan2
- C2orf42 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 119/321 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs552906288, COSV52450411; called by muse, mutect2, varscan2
- C3 | c.3118G>T p.E1040* | Nonsense Mutation (SNP) | VAF 256/695 reads (37%) | catalogued as COSV99836622; called by muse, mutect2, varscan2
- C3orf20 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 568/1276 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as rs186405280; called by muse, mutect2, varscan2
- C5orf15 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 468/1071 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs761369399, COSV99198324; called by muse, mutect2, varscan2
- C8orf37 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 294/808 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145542989, COSV54413698; called by muse, varscan2
- CA10 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 368/900 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.625); catalogued as rs777074047, COSV53336786; called by muse, mutect2, varscan2
- CA11 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 47/911 reads (5%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.98); catalogued as rs1319180333; called by muse, mutect2
- CABIN1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 418/1099 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs1013805114, COSV54077801; called by muse, mutect2, varscan2
- CACHD1 | c.3632G>A p.C1211Y | Missense Mutation (SNP) | VAF 286/718 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV51556814; called by muse, mutect2, varscan2
- CACNA1B | c.1783C>A p.L595M | Missense Mutation (SNP) | VAF 392/998 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99499022; called by muse, mutect2, varscan2
- CACNA1E | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 455/1019 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs373647895; called by muse, mutect2, varscan2
- CACNA2D1 | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 427/988 reads (43%) | catalogued as rs1554520384; called by muse, mutect2, varscan2
- CACNB3 | c.1443G>T p.K481N | Missense Mutation (SNP) | VAF 349/830 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV56396963; called by muse, mutect2, varscan2
- CAD | c.6132T>A p.N2044K | Missense Mutation (SNP) | VAF 278/647 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53023208; called by muse, mutect2, varscan2
- CADM4 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 92/924 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs866029846; called by muse, mutect2
- CAMK2G | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 127/314 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59485311; called by muse, mutect2, varscan2
- CAMKK2 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 126/370 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs760434064; called by muse, mutect2, varscan2
- CAND1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 74/546 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV101598292; called by muse, varscan2
- CAPN13 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 278/567 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV99699737; called by muse, mutect2, varscan2
- CAPN5 | c.627-1G>T p.X209_splice (on ENST00000456580; = p.X169_splice on NM_004055.5) | Splice Site (SNP) | VAF 210/471 reads (45%) | catalogued as COSV53685730, COSV99581592; called by muse, mutect2, varscan2
- CARNMT1 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 278/777 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as rs780475621; called by muse, varscan2
- CASKIN2 | c.3031G>T p.V1011L | Missense Mutation (SNP) | VAF 326/822 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs760947385; called by muse, mutect2, varscan2
- CASP4 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 323/834 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV67744850; called by muse, mutect2, varscan2
- CASP8AP2 | c.3572T>C p.L1191S | Missense Mutation (SNP) | VAF 264/636 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs1387594916; called by muse, mutect2, varscan2
- CATSPERE | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 122/1154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs777560918, COSV100835274; called by muse, mutect2, varscan2
- CATSPERZ | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 367/876 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); catalogued as rs1255835646; called by muse, mutect2, varscan2
- CBR3 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 227/487 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV51742187; called by muse, mutect2, varscan2
- CBX2 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 447/978 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs121908256, CM092895; called by muse, mutect2, varscan2
- CBX8 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 322/793 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.3); catalogued as COSV53937731; called by muse, mutect2, varscan2
- CC2D1A | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 468/1042 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370263842; called by muse, varscan2
- CC2D2A | c.3502C>T p.R1168C | Missense Mutation (SNP) | VAF 168/448 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs746694614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CC2D2B | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 385/1037 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1564673958, COSV100729338, COSV100729414; called by muse, mutect2, varscan2
- CCDC14 | c.2675C>T p.A892V (on ENST00000488653; = p.A844V on NM_022757.5) | Missense Mutation (SNP) | VAF 184/1122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756018919, COSV59944301; called by muse, mutect2, varscan2
- CCDC141 | c.4118G>T p.R1373M | Missense Mutation (SNP) | VAF 415/1005 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV55369842; called by muse, mutect2, varscan2
- CCDC141 | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 355/941 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV55373296; called by muse, mutect2, varscan2
- CCDC144A | c.113T>C p.L38S | Missense Mutation (SNP) | VAF 67/630 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); catalogued as rs200445302; called by muse, mutect2, varscan2
- CCDC158 | c.604A>G p.K202E | Missense Mutation (SNP) | VAF 246/651 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66355872; called by muse, mutect2, varscan2
- CCDC168 | c.20896C>T p.H6966Y | Missense Mutation (SNP) | VAF 255/658 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (0.922); catalogued as rs369569351, COSV59424462; called by muse, mutect2, varscan2
- CCDC168 | c.14455C>T p.R4819C | Missense Mutation (SNP) | VAF 59/658 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs372718153; called by muse, mutect2
- CCDC7 | c.3833G>A p.R1278K | Missense Mutation (SNP) | VAF 226/646 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.97); catalogued as rs1004596073; called by muse, varscan2
- CCDC71 | c.1238A>G p.K413R | Missense Mutation (SNP) | VAF 89/774 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as rs1190961442; called by muse, mutect2, varscan2
- CCNA1 | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 284/715 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as COSV55224935; called by muse, mutect2, varscan2
- CCNDBP1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 226/576 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs372656304; called by muse, varscan2
- CCNK | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 268/646 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV66275730; called by muse, mutect2, varscan2
- CCRL2 | c.362A>T p.N121I | Missense Mutation (SNP) | VAF 267/662 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs770582861; called by muse, mutect2, varscan2
- CCRL2 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 118/797 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.22); catalogued as rs974835507; called by muse, mutect2, varscan2
- CD101 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 308/716 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV56720225; called by mutect2, varscan2
- CD163 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 122/308 reads (40%) | catalogued as COSV63138419; called by muse, mutect2, varscan2
- CD22 | c.1964G>A p.G655D | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50049765; called by muse, mutect2, varscan2
- CD244 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 204/388 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV59241989; called by muse, mutect2, varscan2
- CD36 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 344/829 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143960084; called by muse, mutect2, varscan2
- CD55 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 546/1321 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99042945; called by muse, mutect2, varscan2
- CDC14A | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 46/838 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1257254693, COSV100326176, COSV60559317; called by muse, mutect2
- CDC42BPA | c.2587-1G>T p.X863_splice | Splice Site (SNP) | VAF 284/614 reads (46%) | catalogued as COSV62018582; called by muse, varscan2
- CDC42BPG | c.2325C>T p.R775= | Splice Region (SNP) | VAF 135/483 reads (28%) | catalogued as rs747609362; called by muse, mutect2, varscan2
- CDC42SE1 | c.218G>T p.W73L | Missense Mutation (SNP) | VAF 241/571 reads (42%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.803); catalogued as COSV61785425; called by muse, mutect2, varscan2
- CDCA3 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 121/299 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs199554560, COSV57528554; called by muse, mutect2, varscan2
- CDH19 | c.2059C>T p.Q687* | Nonsense Mutation (SNP) | VAF 316/782 reads (40%) | catalogued as COSV100052283; called by muse, mutect2, varscan2
- CDH19 | c.1232G>A p.S411N | Missense Mutation (SNP) | VAF 28/515 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.049); catalogued as COSV50966506; called by muse, mutect2
- CDH19 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 30/534 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1230780998, COSV100051278, COSV50956087; called by muse, mutect2
- CEACAM1 | c.1128G>T p.Q376H | Missense Mutation (SNP) | VAF 171/398 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV50725679; called by muse, mutect2, varscan2
- CELF3 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 417/774 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1387164081; called by muse, varscan2
- CELF3 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 446/1054 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as rs1261617630; called by muse, varscan2
- CELSR3 | c.4878G>T p.K1626N | Missense Mutation (SNP) | VAF 52/1262 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99374914; called by muse, mutect2
- CELSR3 | c.3374C>T p.T1125M | Missense Mutation (SNP) | VAF 129/261 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs770801944, COSV51141576; called by muse, mutect2, varscan2
- CELSR3 | c.1757G>T p.S586I | Missense Mutation (SNP) | VAF 22/463 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50860290; called by muse, mutect2
- CENPE | c.3661G>T p.G1221* | Nonsense Mutation (SNP) | VAF 232/572 reads (41%) | catalogued as COSV99476712; called by muse, mutect2, varscan2
- CENPE | c.3361A>G p.R1121G | Missense Mutation (SNP) | VAF 82/894 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs772984712; called by muse, mutect2
- CENPU | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 260/788 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs770566473, COSV55658155; called by muse, mutect2, varscan2
- CEP170 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 351/1081 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs776034367, COSV63732415; called by muse, varscan2
- CEP250 | c.4123G>T p.G1375C | Missense Mutation (SNP) | VAF 366/864 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV61175947; called by muse, mutect2, varscan2
- CEP250 | c.6284G>A p.S2095N | Missense Mutation (SNP) | VAF 105/630 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs781264713; called by muse, mutect2, varscan2
- CEP290 | c.635dup p.N212Kfs*3 | Frame Shift Ins (INS) | VAF 269/693 reads (39%) | catalogued as rs769091629; called by mutect2, varscan2
- CEP63 | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 393/997 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV59676032; called by muse, mutect2, varscan2
- CERS6 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 474/1117 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs779093085; called by muse, mutect2, varscan2
- CFAP46 | c.6090G>T p.R2030S | Missense Mutation (SNP) | VAF 122/351 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); catalogued as COSV99585622; called by muse, mutect2, varscan2
- CFTR | c.3407C>T p.A1136V | Missense Mutation (SNP) | VAF 379/972 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1562916044, CM158228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGN | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 433/1054 reads (41%) | catalogued as COSV99641780; called by muse, mutect2, varscan2
- CHD1 | c.2497-5dup | Splice Region (INS) | VAF 152/484 reads (31%) | catalogued as rs1333454417; called by mutect2, varscan2
- CHD7 | c.3379-1G>T p.X1127_splice | Splice Site (SNP) | VAF 352/752 reads (47%) | catalogued as CS126662; called by muse, mutect2, varscan2
- CHD9 | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 455/1156 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs369492840; called by muse, mutect2, varscan2
- CHRD | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 321/805 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1321881115, COSV99200248; called by muse, mutect2, varscan2
- CHRM5 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 28/784 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67247217; called by muse, mutect2
- CHTF18 | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 326/734 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1364059783; called by muse, mutect2, varscan2
- CLASP1 | c.4589C>A p.S1530Y | Missense Mutation (SNP) | VAF 340/879 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV55337369; called by muse, mutect2, varscan2
- CLCN7 | c.1798-1G>T p.X600_splice | Splice Site (SNP) | VAF 184/480 reads (38%) | catalogued as CS142894; called by muse, mutect2, varscan2
- CLCNKB | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 283/908 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100990534; called by muse, mutect2, varscan2
- CLEC16A | c.2791G>T p.A931S | Missense Mutation (SNP) | VAF 45/1038 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV55491258; called by muse, mutect2
- CLIC2 | c.58-1G>T p.X20_splice | Splice Site (SNP) | VAF 134/157 reads (85%) | catalogued as COSV58937291; called by muse, mutect2, varscan2
- CLSPN | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 297/806 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs375491971; called by muse, mutect2, varscan2
- CLTCL1 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 280/736 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs370323620; called by muse, mutect2
- CMTR1 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 169/420 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs773946187, COSV65089303; called by muse, mutect2, varscan2
- CNDP2 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 271/671 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs752258037, COSV100159130; called by muse, mutect2, varscan2
- CNNM1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 193/381 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.102); catalogued as rs761668078; called by muse, mutect2, varscan2
- CNTLN | c.2000G>T p.R667I | Missense Mutation (SNP) | VAF 292/695 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs1290538889; called by muse, mutect2, varscan2
- CNTN1 | c.1448C>T p.T483I | Missense Mutation (SNP) | VAF 272/720 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774877474; called by muse, varscan2
- CNTN3 | c.830A>G p.K277R | Missense Mutation (SNP) | VAF 400/1064 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV55181896; called by muse, mutect2, varscan2
- CNTNAP3B | c.2136G>A p.W712* | Nonsense Mutation (SNP) | VAF 126/680 reads (19%) | catalogued as rs757825836; called by muse, mutect2, varscan2
- COL11A1 | c.2341-1G>T p.X781_splice | Splice Site (SNP) | VAF 292/700 reads (42%) | catalogued as COSV62183330; called by muse, mutect2, varscan2
- COL17A1 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 86/680 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs767281533; called by muse, mutect2, varscan2
- COL1A1 | c.3452G>A p.G1151D | Missense Mutation (SNP) | VAF 481/1145 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs72656321, CM890033; called by muse, mutect2, varscan2
- COL22A1 | c.4601C>A p.P1534H | Missense Mutation (SNP) | VAF 44/756 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57330677; called by muse, mutect2
- COL24A1 | c.3149G>A p.G1050E | Missense Mutation (SNP) | VAF 211/599 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65308246; called by muse, mutect2, varscan2
- COL24A1 | c.1825G>A p.G609S | Missense Mutation (SNP) | VAF 312/846 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240943885; called by muse, varscan2
- COL26A1 | c.1164C>T p.H388= (on ENST00000313669 / NM_001278563.3; = p.H386= on NM_133457.4) | Splice Region (SNP) | VAF 182/441 reads (41%) | catalogued as rs754200239; called by muse, mutect2, varscan2
- COL26A1 | c.1282G>A p.D428N (on ENST00000313669 / NM_001278563.3; = p.D426N on NM_133457.4) | Missense Mutation (SNP) | VAF 367/853 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.059); catalogued as rs768265357; called by muse, mutect2, varscan2
- COL5A1 | c.4513C>A p.L1505I | Missense Mutation (SNP) | VAF 125/1186 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV65668119; called by muse, mutect2, varscan2
- COL5A2 | c.3091C>T p.P1031S | Missense Mutation (SNP) | VAF 351/831 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs187336363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 311/786 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs780474437; called by muse, mutect2, varscan2
- COL6A6 | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 259/727 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.603); catalogued as rs867180544; called by muse, mutect2, varscan2
- COL7A1 | c.7883G>T p.R2628L | Missense Mutation (SNP) | VAF 479/1140 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV56476842; called by muse, mutect2, varscan2
- COL7A1 | c.3841G>A p.G1281S | Missense Mutation (SNP) | VAF 454/1067 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs569641113; called by muse, mutect2, varscan2
- COL9A2 | c.809G>T p.R270M | Missense Mutation (SNP) | VAF 70/736 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV65607411; called by muse, mutect2
- COMP | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 310/734 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.315); catalogued as rs779774621; called by muse, varscan2
- COMP | c.440C>A p.P147Q | Missense Mutation (SNP) | VAF 108/1981 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778825368, COSV55876847; called by muse, mutect2
- COMTD1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 34/921 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs940698501; called by muse, mutect2
- CPB1 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 284/755 reads (38%) | catalogued as rs1473489929; called by muse, mutect2, varscan2
- CPB1 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 233/552 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51576785; called by muse, varscan2
- CPLX4 | c.365C>A p.S122Y | Missense Mutation (SNP) | VAF 188/472 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100231516, COSV55314238; called by mutect2, varscan2
- CPNE8 | c.1437G>A p.M479I | Missense Mutation (SNP) | VAF 202/599 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1404165216, COSV58842313, COSV58848917; called by muse, mutect2, varscan2
- CPT1A | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 292/708 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as rs752483676; called by muse, mutect2, varscan2
- CPT1C | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 123/650 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761961236, COSV54919211; called by muse, mutect2, varscan2
- CPXM1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 283/705 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868316533; called by muse, mutect2, varscan2
- CRACR2A | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 372/829 reads (45%) | catalogued as COSV61540971; called by muse, mutect2, varscan2
- CRB1 | c.2833G>T p.G945* | Nonsense Mutation (SNP) | VAF 392/949 reads (41%) | catalogued as COSV66331163; called by muse, mutect2, varscan2
- CREB5 | c.214G>A p.V72M (on ENST00000357727 / NM_182898.4; = p.V65M on NM_004904.3) | Missense Mutation (SNP) | VAF 588/1479 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754514486, COSV100745006; called by muse, mutect2, varscan2
- CRIM1 | c.991+2T>A p.X331_splice | Splice Site (SNP) | VAF 45/390 reads (12%) | catalogued as COSV54865024; called by muse, mutect2, varscan2
- CRK | c.683C>A p.T228N | Missense Mutation (SNP) | VAF 200/509 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV56032103; called by muse, varscan2
- CROCC | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 413/1866 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs746785024, COSV65013471; called by muse, mutect2, varscan2
- CROCC2 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 531/1288 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1273524639; called by muse, mutect2, varscan2
- CRYBG1 | c.3835T>A p.S1279T | Missense Mutation (SNP) | VAF 289/655 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.64); catalogued as rs1455256335; called by muse, mutect2, varscan2
- CRYL1 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 370/919 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100004373; called by muse, mutect2, varscan2
- CSDC2 | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 244/462 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); catalogued as COSV99348149; called by muse, mutect2, varscan2
- CSF2RB | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 269/746 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1449386315; called by muse, mutect2, varscan2
- CSMD2 | c.8239C>T p.R2747C | Missense Mutation (SNP) | VAF 283/718 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs933232480, COSV53945050; called by muse, mutect2, varscan2
- CSMD2 | c.5366C>T p.A1789V | Missense Mutation (SNP) | VAF 409/1000 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53925946; called by muse, mutect2, varscan2
- CSMD2 | c.3910G>T p.A1304S | Missense Mutation (SNP) | VAF 235/572 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV53903637; called by muse, varscan2
- CSMD3 | c.9299G>A p.G3100D (on ENST00000297405 / NM_001363185.1; = p.G2931D on NM_052900.3) | Missense Mutation (SNP) | VAF 372/898 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52184151; called by muse, varscan2
- CTCF | c.1210del p.X404_splice | Splice Site (DEL) | VAF 114/250 reads (46%) | catalogued as COSV50519231; called by mutect2, varscan2
- CTDP1 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 242/608 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs371862690; called by muse, mutect2, varscan2
- CTIF | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 297/654 reads (45%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs375153721, COSV99837394; called by muse, mutect2, varscan2
- CTRC | c.465C>A p.C155* | Nonsense Mutation (SNP) | VAF 22/501 reads (4%) | catalogued as COSV65621533; called by muse, mutect2
- CTSG | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 274/673 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53534999; called by muse, mutect2, varscan2
- CUL5 | c.1967C>T p.S656L | Missense Mutation (SNP) | VAF 388/1033 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV67608619; called by muse, mutect2, varscan2
- CUTC | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 226/540 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as rs751765874; called by muse, mutect2, varscan2
- CUX1 | c.2907G>T p.K969N | Missense Mutation (SNP) | VAF 50/454 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99471120; called by muse, mutect2, varscan2
- CWC27 | c.496-1G>T p.X166_splice | Splice Site (SNP) | VAF 222/551 reads (40%) | catalogued as rs1345018607; called by muse, varscan2
- CYBA | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 162/385 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.091); catalogued as rs1291407392; called by muse, mutect2
- CYHR1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 472/1067 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs1013044207; called by muse, mutect2, varscan2
- CYLD | c.2165dup p.N722Kfs*2 | Frame Shift Ins (INS) | VAF 268/666 reads (40%) | catalogued as rs1219062549; called by mutect2, varscan2
- CYP11B1 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 470/1106 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.434); catalogued as rs1253405188; called by muse, mutect2, varscan2
- CYP17A1 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 70/701 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as COSV100882124; called by muse, mutect2
- CYP2A6 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 268/964 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1383248905; called by muse, varscan2
- CYP2S1 | c.1012del p.A338Lfs*7 | Frame Shift Del (DEL) | VAF 60/462 reads (13%) | catalogued as rs998617574; called by mutect2, varscan2
- CYP4Z1 | c.1065C>A p.T355= | Splice Region (SNP) | VAF 146/342 reads (43%) | catalogued as rs1171214837; called by muse, varscan2
- CYP8B1 | c.1299G>T p.W433C | Missense Mutation (SNP) | VAF 375/901 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296000; called by muse, mutect2, varscan2
- DAAM1 | c.1628C>A p.S543Y | Missense Mutation (SNP) | VAF 179/527 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as COSV62839913; called by muse, mutect2, varscan2
- DAAM2 | c.2161C>A p.P721T | Missense Mutation (SNP) | VAF 495/1184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51316273; called by muse, mutect2, varscan2
- DAB2 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 366/948 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as rs901530306; called by muse, mutect2, varscan2
- DACH1 | c.1753G>A p.A585T (on ENST00000619232 / NM_001366712.1; = p.A331T on NM_004392.6) | Missense Mutation (SNP) | VAF 358/824 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs751897642; called by muse, mutect2, varscan2
- DACT1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 331/819 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as rs1191859146, COSV100242029; called by muse, mutect2, varscan2
- DACT2 | c.249C>T p.S83= | Splice Region (SNP) | VAF 349/854 reads (41%) | catalogued as COSV100829217; called by muse, mutect2, varscan2
- DAPK2 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 493/1278 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs766325954, COSV56048990; called by muse, mutect2, varscan2
- DCHS1 | c.4312C>T p.R1438C | Missense Mutation (SNP) | VAF 170/357 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs578039974; called by muse, mutect2, varscan2
- DCLK1 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 244/631 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs146043148, COSV55216921; called by muse, mutect2, varscan2
- DCN | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 386/1014 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs763988753; called by muse, mutect2, varscan2
- DCP2 | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 132/890 reads (15%) | catalogued as COSV66616176; called by muse, varscan2
- DDB1 | c.2584G>A p.A862T | Missense Mutation (SNP) | VAF 303/735 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as rs139330194; called by muse, varscan2
- DDX17 | c.1319G>T p.R440I | Missense Mutation (SNP) | VAF 348/902 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV99318947; called by muse, mutect2, varscan2
- DEK | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV52809265; called by mutect2, varscan2
- DEK | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 481/1105 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.159); catalogued as rs764983042; called by muse, mutect2, varscan2
- DELE1 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 431/1107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519948; called by muse, mutect2, varscan2
- DENND1B | c.1814C>T p.T605M | Missense Mutation (SNP) | VAF 248/562 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.681); catalogued as rs200671323; called by muse, mutect2, varscan2
- DENND4B | c.318-1G>A p.X106_splice | Splice Site (SNP) | VAF 161/364 reads (44%) | catalogued as COSV57845253; called by muse, mutect2, varscan2
- DEPDC5 | c.*701-1G>T | Splice Site (SNP) | VAF 226/640 reads (35%) | catalogued as COSV56697411; called by muse, mutect2, varscan2
- DGKB | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 322/751 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51804942; called by muse, mutect2, varscan2
- DGKQ | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 265/550 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs748800103; called by muse, mutect2, varscan2
- DGUOK | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 405/966 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs138683121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHCR24 | c.494-1G>T p.X165_splice | Splice Site (SNP) | VAF 103/951 reads (11%) | catalogued as rs1353973009; called by muse, mutect2, varscan2
- DHTKD1 | c.2416G>A p.V806M | Missense Mutation (SNP) | VAF 406/992 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs763567671, COSV53808149; called by muse, varscan2
- DHX16 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 435/1000 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs765108722; called by muse, mutect2, varscan2
- DICER1 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 279/718 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs965350808, COSV100602724; called by muse, mutect2, varscan2
- DIDO1 | c.6110G>A p.R2037Q | Missense Mutation (SNP) | VAF 441/1072 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs1240374274; called by muse, mutect2, varscan2
- DIDO1 | c.1660G>T p.G554C | Missense Mutation (SNP) | VAF 515/1262 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV56624269; called by muse, mutect2, varscan2
- DIP2C | c.3484C>T p.R1162C | Missense Mutation (SNP) | VAF 325/826 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs767258769, COSV55153642; called by muse, mutect2, varscan2
- DLC1 | c.1825C>T p.P609S (on ENST00000276297 / NM_001348081.2; = p.P172S on NM_006094.5) | Missense Mutation (SNP) | VAF 252/542 reads (46%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs763764390; called by muse, mutect2, varscan2
- DLG5 | c.4528C>A p.L1510M | Missense Mutation (SNP) | VAF 401/986 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as COSV64947654; called by muse, mutect2, varscan2
- DLG5 | c.548G>T p.R183M | Missense Mutation (SNP) | VAF 169/415 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV64948208; called by muse, mutect2, varscan2
- DLGAP4 | c.1768C>A p.L590M | Missense Mutation (SNP) | VAF 321/749 reads (43%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.996); catalogued as COSV59413840; called by muse, mutect2, varscan2
- DLK1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs751083673, COSV57991268; called by muse, mutect2, varscan2
- DMD | c.10683G>T p.E3561D | Missense Mutation (SNP) | VAF 243/279 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374369906, COSV100629160; called by muse, mutect2, varscan2
- DMD | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 410/479 reads (86%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs766723466, COSV99923179; called by muse, mutect2, varscan2
- DMXL1 | c.3746C>T p.P1249L | Missense Mutation (SNP) | VAF 176/427 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60705530; called by muse, mutect2
- DMXL1 | c.5237G>A p.R1746H | Missense Mutation (SNP) | VAF 349/884 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs779107340, COSV100224132; called by muse, mutect2, varscan2
- DNAH1 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 282/725 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV70237183; called by muse, mutect2, varscan2
- DNAH1 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 255/651 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs200623391, COSV70227029; called by muse, mutect2, varscan2
- DNAH1 | c.3837G>T p.K1279N | Missense Mutation (SNP) | VAF 366/897 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs1460748933; called by muse, mutect2, varscan2
- DNAH10 | c.5741G>A p.C1914Y (on ENST00000409039; = p.C1853Y on NM_207437.3) | Missense Mutation (SNP) | VAF 342/820 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766967012, COSV68996755; called by muse, mutect2, varscan2
- DNAH10 | c.12070C>T p.R4024C (on ENST00000409039; = p.R3963C on NM_207437.3) | Missense Mutation (SNP) | VAF 263/645 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755346965, CM153153; called by muse, mutect2, varscan2
- DNAH11 | c.12178C>A p.L4060M | Missense Mutation (SNP) | VAF 486/1088 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60938871; called by muse, mutect2, varscan2
- DNAH14 | c.9365C>T p.T3122I (on ENST00000445597; = p.T4130I on NM_001367479.1) | Missense Mutation (SNP) | VAF 354/799 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); catalogued as rs750234608; called by muse, mutect2, varscan2
- DNAH17 | c.2939C>T p.A980V | Missense Mutation (SNP) | VAF 205/529 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs1376759762; called by muse, mutect2, varscan2
- DNAH2 | c.4483C>T p.R1495W | Missense Mutation (SNP) | VAF 289/672 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs776753676; called by muse, varscan2
- DNAH5 | c.10930G>A p.G3644R | Missense Mutation (SNP) | VAF 410/968 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54218549; called by muse, mutect2, varscan2
- DNAH6 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 218/610 reads (36%) | catalogued as COSV99407712; called by muse, mutect2, varscan2
- DNAH9 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 193/373 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs984430231, COSV99306853; called by muse, mutect2, varscan2
- DNAJC11 | c.24G>T p.E8D | Missense Mutation (SNP) | VAF 328/735 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1332234603; called by muse, mutect2, varscan2
- DNAJC13 | c.4156G>T p.D1386Y | Missense Mutation (SNP) | VAF 236/542 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs775866155; called by muse, mutect2, varscan2
- DNAJC22 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 164/339 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101222524; called by muse, mutect2, varscan2
- DNAJC3 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 126/386 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372983173; called by muse, mutect2, varscan2
- DNHD1 | c.6498T>G p.Y2166* | Nonsense Mutation (SNP) | VAF 370/900 reads (41%) | catalogued as rs61729699; called by muse, mutect2, varscan2
- DNM3 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 214/540 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as rs759897946; called by muse, mutect2, varscan2
- DNMT3A | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 277/733 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs771499883; called by muse, mutect2, varscan2
- DOCK1 | c.4519A>G p.M1507V | Missense Mutation (SNP) | VAF 353/823 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs1259544454; called by muse, mutect2, varscan2
- DOCK6 | c.1972-6C>T | Splice Region (SNP) | VAF 243/482 reads (50%) | catalogued as COSV99371031; called by muse, mutect2, varscan2
- DOCK6 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 279/651 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV53914690; called by muse, mutect2, varscan2
- DOCK8 | c.4277G>A p.S1426N | Missense Mutation (SNP) | VAF 395/941 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs779180930; called by muse, mutect2, varscan2
- DOCK9 | c.2293G>A p.G765R (on ENST00000376460 / NM_001366676.2; = p.G766R on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 276/677 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs370847473; called by muse, varscan2
- DOT1L | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 249/616 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67112579; called by muse, mutect2, varscan2
- DPYSL3 | c.667C>A p.H223N | Missense Mutation (SNP) | VAF 31/762 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100574875; called by muse, mutect2
- DRC7 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 356/884 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370833826; called by muse, mutect2, varscan2
- DRD2 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 208/446 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100669385; called by muse, mutect2, varscan2
- DROSHA | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 380/917 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1226092566; called by muse, mutect2, varscan2
- DSC1 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 323/806 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV57145300; called by muse, mutect2, varscan2
- DSCAML1 | c.2224C>T p.R742C (on ENST00000321322; = p.R682C on NM_020693.4) | Missense Mutation (SNP) | VAF 293/722 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as rs747779784, COSV58387002; called by muse, mutect2, varscan2
- DSCAML1 | c.620T>C p.L207P (on ENST00000321322; = p.L147P on NM_020693.4) | Missense Mutation (SNP) | VAF 64/620 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs748651790, COSV100356631; called by muse, varscan2
- DSP | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 288/829 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs772551736, COSV101131380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTX3 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 241/690 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99678035; called by muse, varscan2
- DUOX1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 268/776 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs149693969; called by muse, varscan2
- DUS2 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 179/453 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV62710092; called by muse, mutect2, varscan2
- DYNC2H1 | c.5689A>G p.I1897V | Missense Mutation (SNP) | VAF 170/411 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs765442689, COSV62097183; called by muse, mutect2, varscan2
- DYNC2I2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 241/602 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV101020957; called by muse, mutect2, varscan2
- DYSF | c.4753G>A p.V1585I | Missense Mutation (SNP) | VAF 296/748 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99063652; called by muse, varscan2
- DZIP1 | c.1687C>T p.R563C (on ENST00000347108; = p.R544C on NM_014934.5) | Missense Mutation (SNP) | VAF 295/856 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs539519755, COSV61265134; called by muse, mutect2, varscan2
- E2F3 | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 303/756 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV60898171; called by muse, mutect2, varscan2
- E2F8 | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 228/588 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51465843; called by muse, varscan2
- E4F1 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 316/791 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749481310; called by muse, mutect2, varscan2
- ECRG4 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 303/671 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV53001176; called by mutect2, varscan2
- EEF2KMT | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 260/742 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as rs534671907, COSV52157955; called by muse, varscan2
- EEFSEC | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 276/731 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV54633830; called by muse, mutect2, varscan2
- EFCAB6 | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 313/912 reads (34%) | catalogued as rs369031858; called by muse, mutect2, varscan2
- EFHB | c.1960A>G p.T654A | Missense Mutation (SNP) | VAF 217/596 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1438602799; called by muse, mutect2, varscan2
- EFNB2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 484/1224 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as rs777601389, COSV99808537; called by muse, mutect2, varscan2
- EFNB3 | c.29del p.G10Afs*49 | Frame Shift Del (DEL) | VAF 388/840 reads (46%) | catalogued as COSV99872906; called by mutect2, varscan2
- EFR3A | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 366/896 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99603756; called by muse, mutect2, varscan2
- EHBP1 | c.2266dup p.T756Nfs*8 | Frame Shift Ins (INS) | VAF 316/745 reads (42%) | catalogued as rs1379721094; called by mutect2, varscan2
- EIF2AK3 | c.2050C>T p.L684F | Missense Mutation (SNP) | VAF 307/787 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs770672534; called by muse, mutect2, varscan2
- EIF2AK4 | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 310/857 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs202241343; called by muse, mutect2, varscan2
- EIF4H | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 124/1431 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1554709368; called by muse, mutect2
- ELANE | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 175/365 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs749675557; called by muse, mutect2, varscan2
- ELMO3 | c.849G>T p.K283N (on ENST00000652269; = p.K230N on NM_024712.5) | Missense Mutation (SNP) | VAF 476/1129 reads (42%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.866); catalogued as COSV62607347; called by muse, mutect2, varscan2
- ELOVL4 | c.937G>T p.G313* | Nonsense Mutation (SNP) | VAF 40/708 reads (6%) | catalogued as COSV63953827; called by muse, mutect2
- ELOVL5 | c.756G>T p.Q252H | Missense Mutation (SNP) | VAF 188/443 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.297); catalogued as COSV100439477; called by muse, mutect2, varscan2
- EMCN | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 417/1072 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.283); catalogued as rs749194605; called by muse, mutect2, varscan2
- EMILIN1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 82/833 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs753862645, CM160483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EML5 | c.4594G>A p.V1532M (on ENST00000380664; = p.V1540M on NM_183387.3) | Missense Mutation (SNP) | VAF 312/765 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61349435; called by muse, varscan2
- EMSY | c.3185C>T p.P1062L | Missense Mutation (SNP) | VAF 392/1073 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs761146250, COSV100595525; called by muse, mutect2, varscan2
- ENPP2 | c.2506C>A p.L836M (on ENST00000075322 / NM_001040092.3; = p.L888M on NM_006209.5) | Missense Mutation (SNP) | VAF 289/721 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99309204; called by muse, varscan2
- ENPP2 | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 239/491 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as rs1043447285, COSV50019890; called by muse, mutect2, varscan2
- ENTHD1 | c.1102T>A p.S368T | Missense Mutation (SNP) | VAF 46/685 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57321110; called by muse, mutect2
- EOGT | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 338/844 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs750423818, COSV55151789; called by muse, mutect2, varscan2
- EOLA2 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 504/589 reads (86%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV62207364; called by muse, mutect2, varscan2
- EP400 | c.4528G>A p.A1510T | Missense Mutation (SNP) | VAF 413/939 reads (44%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs753578754, COSV57778869; called by muse, mutect2, varscan2
- EPHA1 | c.2826G>T p.M942I | Missense Mutation (SNP) | VAF 542/1146 reads (47%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.542); catalogued as COSV99314887; called by muse, mutect2, varscan2
- EPHA4 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 690/1649 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1559300040, COSV99917212; called by muse, mutect2, varscan2
- EPHA5 | c.1202A>G p.H401R | Missense Mutation (SNP) | VAF 332/874 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.109); catalogued as COSV56662172; called by muse, mutect2, varscan2
- EPHA6 | c.2501G>T p.R834M (on ENST00000389672 / NM_001080448.3; = p.R226M on NM_173655.4) | Missense Mutation (SNP) | VAF 267/635 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.358); catalogued as COSV101060754; called by muse, mutect2, varscan2
- EPHA8 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 272/738 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); catalogued as rs755571143, COSV51264046; called by muse, mutect2, varscan2
- EPHX1 | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 710/1634 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs747236806, COSV99689195; called by muse, mutect2, varscan2
- EPPK1 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 122/282 reads (43%) | catalogued as rs782289184; called by muse, mutect2, varscan2
- EPX | c.704T>A p.L235Q | Missense Mutation (SNP) | VAF 211/454 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56599684; called by muse, mutect2, varscan2
- EPX | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 309/851 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1003830294, COSV56594781; called by muse, mutect2, varscan2
- EPYC | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 286/740 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764617595, COSV53800740, COSV99664692; called by muse, varscan2
- ERP44 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 216/496 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1219876322; called by muse, varscan2
- ERV3-1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 274/740 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs1349669968; called by muse, mutect2, varscan2
- ESRP2 | c.1427G>A p.C476Y (on ENST00000565858 / NM_001365264.1; = p.C466Y on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 233/516 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1200817796; called by muse, mutect2, varscan2
- ETAA1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 263/670 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226894470, COSV99713032; called by muse, mutect2, varscan2
- ETNK1 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 135/837 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99075351; called by muse, mutect2, varscan2
- EVC | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 386/1075 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.234); catalogued as rs1318878744; called by muse, mutect2, varscan2
- EXD1 | c.878C>A p.T293N | Missense Mutation (SNP) | VAF 148/369 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV59252931; called by muse, mutect2, varscan2
- EYS | c.8435T>C p.V2812A (on ENST00000370621 / NM_001292009.1; = p.V2791A on NM_001142800.2) | Missense Mutation (SNP) | VAF 58/1142 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.129); catalogued as COSV65481360; called by muse, mutect2
- EZH1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 289/630 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); catalogued as rs1235417794; called by muse, mutect2, varscan2
- F13A1 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 252/434 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.722); catalogued as rs747218826, COSV53553411; called by muse, mutect2, varscan2
- F8 | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 348/398 reads (87%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as CD088377; called by muse, mutect2, varscan2
- FADS6 | c.905G>T p.S302I | Missense Mutation (SNP) | VAF 362/829 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59602056; called by muse, mutect2, varscan2
- FAM107A | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 166/380 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs754770704, COSV100723978; called by muse, mutect2, varscan2
- FAM107B | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 242/565 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV51683794; called by muse, mutect2, varscan2
- FAM13A | c.856A>G p.R286G | Missense Mutation (SNP) | VAF 184/452 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs763740694, COSV52005405; called by muse, varscan2
- FAM161A | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 371/871 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.88); catalogued as COSV56768062; called by muse, mutect2, varscan2
- FAM184A | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 364/867 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100137289; called by muse, mutect2, varscan2
- FAM186A | c.3464C>T p.P1155L | Missense Mutation (SNP) | VAF 178/454 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs865838338, COSV59245749, COSV59247631; called by mutect2, varscan2
- FAM186A | c.2261dup p.V755Gfs*16 | Frame Shift Ins (INS) | VAF 250/644 reads (39%) | catalogued as rs1325556099; called by mutect2, varscan2
- FAM187B | c.1082G>T p.R361I | Missense Mutation (SNP) | VAF 219/538 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs764787341; called by muse, mutect2, varscan2
- FAM20A | c.83G>T p.W28L | Missense Mutation (SNP) | VAF 489/1151 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs867622412; called by muse, mutect2, varscan2
- FAM83H | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 324/865 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.299); catalogued as rs782700536, COSV66353964; called by muse, mutect2, varscan2
- FANCB | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 394/455 reads (87%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.497); catalogued as rs757202355, COSV60758828; called by muse, mutect2, varscan2
- FANCD2 | c.995C>A p.S332* | Nonsense Mutation (SNP) | VAF 299/726 reads (41%) | catalogued as COSV99811540; called by muse, varscan2
- FAR1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 299/732 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.075); catalogued as rs1169997159, COSV100701614; called by muse, mutect2, varscan2
- FAT2 | c.9562C>A p.R3188S | Missense Mutation (SNP) | VAF 366/967 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV55826239; called by muse, mutect2, varscan2
- FAT4 | c.1586G>T p.S529I | Missense Mutation (SNP) | VAF 369/860 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67899031; called by muse, mutect2, varscan2
- FBN2 | c.8099C>T p.S2700L | Missense Mutation (SNP) | VAF 186/378 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as rs776788539; called by muse, varscan2
- FBXL17 | c.1624C>A p.L542I | Missense Mutation (SNP) | VAF 219/616 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62851165; called by muse, mutect2, varscan2
- FBXL17 | c.1415G>A p.G472D | Missense Mutation (SNP) | VAF 378/930 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV62862166; called by muse, varscan2
- FBXL19 | c.614dup p.E206Gfs*17 | Frame Shift Ins (INS) | VAF 210/558 reads (38%) | catalogued as rs745385709; called by mutect2, varscan2
- FBXL6 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 223/487 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as rs782500969, COSV57353220; called by muse, mutect2, varscan2
- FBXL8 | c.1075C>T p.L359F | Missense Mutation (SNP) | VAF 377/867 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1404994191; called by muse, mutect2, varscan2
- FBXO38 | c.2479G>T p.G827C | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.642); catalogued as COSV57026092; called by muse, varscan2
- FBXO47 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 342/853 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100960606, COSV65242140; called by muse, mutect2, varscan2
- FBXO9 | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 113/1034 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs772341752; called by muse, mutect2, varscan2
- FCGBP | c.10564G>T p.G3522W | Missense Mutation (SNP) | VAF 37/905 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142550475; called by muse, mutect2
- FDXACB1 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 199/650 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs782651951, COSV52788677; called by muse, varscan2
- FGA | c.1541C>A p.P514H | Missense Mutation (SNP) | VAF 315/722 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as CD035514, COSV57393503, COSV57402272; called by muse, mutect2, varscan2
- FGD2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 407/937 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs762784794, COSV51462297; called by muse, mutect2, varscan2
- FGD3 | c.2107C>A p.H703N | Missense Mutation (SNP) | VAF 244/584 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100490807; called by mutect2, varscan2
- FGD5 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 200/453 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV53247963; called by muse, mutect2, varscan2
- FGFR4 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 224/536 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776973649, COSV52801328; called by muse, mutect2, varscan2
- FH | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 309/760 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM033615; called by muse, mutect2, varscan2
- FLAD1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 149/318 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); catalogued as rs1319776376; called by muse, mutect2, varscan2
- FLG | c.10511C>T p.S3504L | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV64251559; called by muse, mutect2, varscan2
- FLII | c.2537A>G p.Y846C | Missense Mutation (SNP) | VAF 116/1094 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100375303; called by muse, mutect2, varscan2
- FLNB | c.3593C>T p.T1198M | Missense Mutation (SNP) | VAF 156/334 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as rs963229056, COSV55869550; called by muse, varscan2
- FLNC | c.2642G>T p.G881V | Missense Mutation (SNP) | VAF 453/1017 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs377095070, COSV57956060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.3371C>T p.T1124M | Missense Mutation (SNP) | VAF 294/714 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375013141, COSV57958626; called by muse, mutect2, varscan2
- FLOT2 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 462/1182 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67529387; called by muse, mutect2, varscan2
- FLOT2 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 370/900 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as rs1170518120; called by muse, mutect2, varscan2
- FLT4 | c.1726C>A p.L576M | Missense Mutation (SNP) | VAF 243/597 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56113192; called by muse, mutect2, varscan2
- FLYWCH2 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 274/676 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1157708644; called by muse, mutect2, varscan2
- FMN2 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 447/958 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as rs747224830; called by muse, mutect2, varscan2
- FMO5 | c.487+1G>A p.X163_splice | Splice Site (SNP) | VAF 260/611 reads (43%) | catalogued as rs782356903; called by muse, mutect2, varscan2
- FNBP1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 148/334 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs991955698; called by muse, mutect2, varscan2
- FNDC7 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 352/972 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1246945645; called by muse, mutect2
- FOXB1 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 93/957 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68526547; called by muse, mutect2
- FOXD4 | c.833C>A p.P278Q | Missense Mutation (SNP) | VAF 207/1098 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1351717707; called by muse, mutect2, varscan2
- FOXD4L1 | c.842C>A p.P281Q | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV99380875; called by muse, mutect2, varscan2
- FOXN1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 362/842 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs767313142, COSV56883270, COSV99880968; called by muse, varscan2
- FPGT | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 405/1062 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1167410894; called by muse, varscan2
- FRG2B | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 276/1079 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.771); catalogued as rs1487083122; called by muse, varscan2
- FRMD4A | c.1874A>G p.K625R | Missense Mutation (SNP) | VAF 260/639 reads (41%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.98); catalogued as rs1305982717; called by muse, varscan2
- FRY | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 324/774 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs760794264; called by muse, varscan2
- FRY | c.4317G>A p.W1439* | Nonsense Mutation (SNP) | VAF 312/779 reads (40%) | catalogued as COSV66579387; called by muse, mutect2, varscan2
- FSCN2 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 267/616 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs557443473; called by muse, mutect2, varscan2
- FTCD | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 434/966 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.64); catalogued as rs560811619; called by muse, varscan2
- FUBP1 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 301/734 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53936275; called by muse, mutect2, varscan2
- FUT8 | c.1057C>A p.L353I (on ENST00000360689 / NM_001371534.1; = p.L190I on NM_004480.4) | Missense Mutation (SNP) | VAF 219/586 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as COSV100651348; called by muse, mutect2, varscan2
- FZD3 | c.1925G>T p.S642I | Missense Mutation (SNP) | VAF 253/695 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs1467842934; called by muse, mutect2, varscan2
- GAB4 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 346/806 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68753986; called by muse, mutect2
- GALNT13 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 229/573 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV67218941; called by muse, mutect2, varscan2
- GALNT13 | c.1319A>G p.Q440R | Missense Mutation (SNP) | VAF 400/997 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.052); catalogued as COSV67230667; called by muse, varscan2
- GALNT14 | c.1236-1G>T p.X412_splice | Splice Site (SNP) | VAF 356/794 reads (45%) | catalogued as COSV61110889; called by mutect2, varscan2
- GALNT17 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 219/503 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV61163237; called by muse, mutect2, varscan2
- GALNT2 | c.436A>G p.N146D | Missense Mutation (SNP) | VAF 355/786 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs757622597; called by muse, mutect2, varscan2
- GANC | c.2249C>T p.T750I | Missense Mutation (SNP) | VAF 154/428 reads (36%) | PolyPhen probably damaging (0.953); catalogued as rs370759059; called by muse, varscan2
- GAP43 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 212/569 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100525252; called by muse, mutect2, varscan2
- GAPDH | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 183/522 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1170110177; called by muse, mutect2
- GARRE1 | c.706-1G>A p.X236_splice | Splice Site (SNP) | VAF 144/359 reads (40%) | catalogued as COSV55104332; called by muse, mutect2, varscan2
- GAS2L2 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 50/840 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.035); catalogued as rs370173315; called by muse, mutect2
- GATA6 | c.1351A>G p.T451A | Missense Mutation (SNP) | VAF 239/595 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV52527453; called by muse, mutect2, varscan2
- GATAD2A | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 138/298 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99389792; called by muse, mutect2, varscan2
- GBA2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 188/460 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs368192956, COSV100803430; ClinVar: uncertain significance; called by muse, varscan2
- GBP1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 538/1226 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65083324; called by muse, varscan2
- GBP4 | c.242C>A p.P81H | Missense Mutation (SNP) | VAF 184/365 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV100864435; called by muse, mutect2, varscan2
- GCFC2 | c.1620G>T p.K540N | Missense Mutation (SNP) | VAF 310/794 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV58083514; called by muse, mutect2, varscan2
- GCH1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 227/534 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD013158; called by muse, mutect2, varscan2
- GCHFR | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 535/1271 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1355706914, COSV99549203; called by muse, mutect2, varscan2
- GCLC | c.1553C>T p.T518I (on ENST00000643939; = p.T516I on NM_001498.4) | Missense Mutation (SNP) | VAF 248/650 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs374629517; called by muse, mutect2, varscan2
- GCN1 | c.6944G>A p.G2315E | Missense Mutation (SNP) | VAF 230/537 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346123587; called by muse, mutect2, varscan2
- GCN1 | c.1112A>G p.H371R | Missense Mutation (SNP) | VAF 39/1062 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1300337713; called by muse, mutect2
- GCN1 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 298/724 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as rs994283197; called by muse, varscan2
- GCNT7 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 246/584 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs999972975; called by muse, mutect2, varscan2
- GDF15 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 168/456 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99416061; called by muse, mutect2, varscan2
- GFOD1 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 349/736 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs763168816, COSV64955232; called by muse, mutect2, varscan2
- GFOD2 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 124/280 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.044); catalogued as rs1172033674; called by muse, mutect2, varscan2
- GFPT1 | c.1529T>C p.M510T (on ENST00000357308 / NM_001244710.2; = p.M492T on NM_002056.4) | Missense Mutation (SNP) | VAF 451/1066 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM110945; called by muse, varscan2
- GIMAP8 | c.805G>T p.G269W | Missense Mutation (SNP) | VAF 377/834 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56232606; called by muse, mutect2, varscan2
- GJA4 | c.213del p.I72Sfs*59 | Frame Shift Del (DEL) | VAF 212/484 reads (44%) | catalogued as COSV60726142; called by mutect2, varscan2
- GLYCTK | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 349/749 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1186216170; called by muse, mutect2, varscan2
- GM2A | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 290/750 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201829650; called by muse, mutect2, varscan2
- GNB5 | c.910A>G p.T304A (on ENST00000261837 / NM_016194.4; = p.T262A on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/535 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV55901364; called by muse, mutect2
- GNG13 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 299/684 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs148166942; called by muse, mutect2, varscan2
- GOLGA6C | c.2010G>T p.R670S | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV100316404, COSV56034959; called by muse, mutect2, varscan2
- GOLGA6L9 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 90/1244 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1168402075; called by muse, mutect2
- GOLGB1 | c.3947C>T p.A1316V | Missense Mutation (SNP) | VAF 286/752 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1317768563; called by muse, varscan2
- GOLM1 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 174/494 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs779660359; called by mutect2, varscan2
- GON4L | c.4855C>T p.R1619* | Nonsense Mutation (SNP) | VAF 103/811 reads (13%) | catalogued as rs1260263684; called by muse, mutect2, varscan2
- GON4L | c.269C>A p.P90Q | Missense Mutation (SNP) | VAF 69/494 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs1444518767; called by muse, mutect2, varscan2
- GORAB | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 81/607 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs185015283; called by muse, mutect2, varscan2
- GPATCH2L | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 258/629 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as rs1446713734; called by muse, mutect2, varscan2
- GPATCH8 | c.3118C>T p.R1040* | Nonsense Mutation (SNP) | VAF 49/436 reads (11%) | catalogued as rs567613406; called by muse, mutect2, varscan2
- GPD2 | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 372/926 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745771373, COSV100133034; called by muse, mutect2, varscan2
- GPR158 | c.1515G>T p.R505S | Missense Mutation (SNP) | VAF 207/464 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100893552; called by muse, mutect2, varscan2
- GPR179 | c.1522G>A p.V508M (on ENST00000621958; = p.V507M on NM_001004334.4) | Missense Mutation (SNP) | VAF 216/495 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as rs757741920; called by muse, mutect2, varscan2
- GPR37 | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 385/967 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1216806022; called by muse, mutect2, varscan2
- GPRIN2 | c.215T>C p.M72T | Missense Mutation (SNP) | VAF 204/858 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1555020427; called by muse, mutect2, varscan2
- GPX5 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 349/855 reads (41%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.326); catalogued as COSV69079809; called by muse, mutect2, varscan2
- GRID2 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 88/1035 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs769386426, COSV99938421; called by muse, mutect2
- GRIK1 | c.2608-1G>T p.X870_splice | Splice Site (SNP) | VAF 74/488 reads (15%) | catalogued as rs769721429, COSV100518107; called by muse, mutect2, varscan2
- GRIK2 | c.436T>G p.Y146D | Missense Mutation (SNP) | VAF 51/639 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV59732488; called by muse, mutect2
- GRIK3 | c.1919G>A p.G640D | Missense Mutation (SNP) | VAF 327/855 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66136978; called by muse, mutect2, varscan2
- GRIN2C | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 119/385 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs776102062, COSV99500574; called by muse, mutect2, varscan2
- GRM7 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 353/1134 reads (31%) | catalogued as rs1390058794, COSV63143649, COSV63161230; called by muse, mutect2, varscan2
- GRM8 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 173/525 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs753153909, COSV58872897; called by muse, mutect2, varscan2
- GSTM3 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 404/866 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs565296303; called by muse, mutect2, varscan2
- GTF3C3 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 485/1182 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.86); catalogued as rs768859221, COSV55832246; called by muse, mutect2, varscan2
- GYS2 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 372/926 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.909); catalogued as rs139031614; called by muse, varscan2
- GZMA | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 183/406 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57112070; called by muse, varscan2
- GZMA | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 231/524 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs72764175; called by muse, varscan2
- H1-6 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 287/653 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV58090792; called by muse, varscan2
- H1-6 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 282/658 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1392158066, COSV100619508; called by muse, varscan2
- H2AC13 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 383/1038 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.378); catalogued as COSV100704458; called by muse, mutect2, varscan2
- H2AZ1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 470/1263 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56455579; called by muse, mutect2, varscan2
- HADHA | c.49A>G p.R17G | Missense Mutation (SNP) | VAF 296/756 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs757561140; called by muse, mutect2, varscan2
- HAL | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 274/732 reads (37%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99701648; called by muse, mutect2, varscan2
- HAND2 | c.283C>G p.P95A | Missense Mutation (SNP) | VAF 208/462 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs75152023; called by mutect2, varscan2
- HCAR2 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 294/1393 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.038); catalogued as rs199511843; called by muse, mutect2, varscan2
- HCAR3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 99/784 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.019); catalogued as rs371201756; called by muse, mutect2, varscan2
- HCST | c.42A>G p.P14= | Splice Region (SNP) | VAF 213/551 reads (39%) | catalogued as rs142787318; called by muse, mutect2, varscan2
- HDAC11 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 386/940 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs368815162; called by muse, mutect2, varscan2
- HDAC5 | c.3061G>T p.A1021S | Missense Mutation (SNP) | VAF 226/595 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV99291120; called by muse, mutect2, varscan2
- HEATR1 | c.1193G>T p.S398I | Missense Mutation (SNP) | VAF 192/511 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV63982763; called by muse, mutect2, varscan2
- HEATR1 | c.773G>T p.R258I | Missense Mutation (SNP) | VAF 279/702 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100857827; called by muse, mutect2, varscan2
- HEATR5A | c.4850A>G p.H1617R | Missense Mutation (SNP) | VAF 128/422 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570444545; called by muse, varscan2
- HEATR5A | c.3943G>A p.V1315M | Missense Mutation (SNP) | VAF 176/470 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1347674420; called by muse, mutect2, varscan2
- HEATR6 | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 41/934 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1262273324, COSV51747461; called by muse, mutect2
- HECW1 | c.2527G>T p.G843W | Missense Mutation (SNP) | VAF 301/791 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67837527; called by muse, mutect2, varscan2
- HEPACAM2 | c.78C>T p.F26= | Splice Region (SNP) | VAF 217/540 reads (40%) | catalogued as rs1210870913; called by muse, mutect2, varscan2
- HERC2 | c.12347G>A p.G4116D | Missense Mutation (SNP) | VAF 476/1089 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55312882; called by muse, mutect2, varscan2
- HEXD | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 214/473 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201473179, COSV60063259; called by muse, mutect2, varscan2
- HGF | c.1045C>A p.L349I | Missense Mutation (SNP) | VAF 179/457 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55944835; called by muse, mutect2, varscan2
- HIP1 | c.3038G>T p.G1013V | Missense Mutation (SNP) | VAF 62/1195 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61192117; called by muse, mutect2
- HIPK1 | c.1408-1G>T p.X470_splice | Splice Site (SNP) | VAF 156/380 reads (41%) | catalogued as COSV61248644; called by muse, mutect2, varscan2
- HIPK1 | c.3126A>C p.Q1042H | Missense Mutation (SNP) | VAF 214/493 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.948); catalogued as COSV61245593; called by muse, mutect2, varscan2
- HIVEP2 | c.6355C>A p.P2119T | Missense Mutation (SNP) | VAF 274/650 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50018560; called by muse, varscan2
- HIVEP2 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 290/750 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); catalogued as COSV99176419; called by muse, varscan2
- HMCN2 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 199/387 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV101132804; called by muse, mutect2, varscan2
- HMMR | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 253/644 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758018522; called by muse, mutect2, varscan2
- HMOX2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 225/584 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs773570009; called by muse, mutect2, varscan2
- HNRNPA1 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 189/730 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52935986; called by muse, mutect2, varscan2
- HNRNPL | c.1560C>A p.I520= | Splice Region (SNP) | VAF 139/293 reads (47%) | catalogued as COSV99670470; called by muse, mutect2, varscan2
- HNRNPR | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 152/437 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1451450921; called by muse, varscan2
- HOXB1 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 136/404 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs753115367, COSV53317459, COSV53318822; called by mutect2, varscan2
- HOXC11 | c.894C>A p.F298L | Missense Mutation (SNP) | VAF 350/871 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.688); catalogued as COSV54532911; called by muse, mutect2, varscan2
- HPS3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 447/1155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202087344; called by muse, mutect2, varscan2
- HPS5 | c.808C>T p.P270S (on ENST00000349215 / NM_181507.2; = p.P156S on NM_007216.4) | Missense Mutation (SNP) | VAF 216/519 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100834448; called by muse, mutect2, varscan2
- HPSE2 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 256/640 reads (40%) | catalogued as rs1213312108; called by muse, varscan2
- HPSE2 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 383/922 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1465062636, COSV100984620; called by muse, mutect2, varscan2
- HRH3 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs200096925; called by muse, mutect2, varscan2
- HRNR | c.3308G>A p.G1103D | Missense Mutation (SNP) | VAF 72/686 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.497); catalogued as rs759328686; called by muse, mutect2, varscan2
- HSD11B1L | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 269/626 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1373912440, COSV100028471; called by muse, mutect2, varscan2
- HSD17B4 | c.589C>A p.L197M (on ENST00000414835 / NM_001199291.3; = p.L172M on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 374/848 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV56334112; called by muse, varscan2
- HSD3B1 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 160/432 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.719); catalogued as COSV52492004; called by muse, mutect2, varscan2
- HSP90AB1 | c.1714G>T p.D572Y | Missense Mutation (SNP) | VAF 178/429 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV62336385; called by muse, mutect2, varscan2
- HSPA13 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 315/1113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1307157337; called by muse, mutect2, varscan2
- HSPB8 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 395/978 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV56139723; called by muse, mutect2, varscan2
- HSPG2 | c.10402G>A p.A3468T | Missense Mutation (SNP) | VAF 292/730 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1013471019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR1A | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 451/1382 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100109304; called by muse, mutect2, varscan2
- HTR2B | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 463/1162 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs769352469, COSV51450053; called by muse, mutect2, varscan2
- HTT | c.8254G>A p.V2752I | Missense Mutation (SNP) | VAF 402/989 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs367721569; called by muse, mutect2, varscan2
- HTT | c.8615C>T p.S2872F | Missense Mutation (SNP) | VAF 364/802 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV61860473; called by muse, mutect2, varscan2
- HUWE1 | c.7330G>A p.D2444N | Missense Mutation (SNP) | VAF 389/455 reads (85%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV53336085; called by muse, mutect2, varscan2
- IBA57 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 483/1107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64511566; called by muse, mutect2, varscan2
- IBTK | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 38/742 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs867395775; called by muse, mutect2
- ICAM5 | c.1157C>T p.T386I | Missense Mutation (SNP) | VAF 309/761 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs772721226; called by muse, mutect2, varscan2
- IFFO1 | c.1089dup p.R364Afs*19 (on ENST00000396840 / NM_001330324.2; = p.R367Afs*19 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 293/826 reads (35%) | catalogued as rs750779916; called by mutect2, varscan2
- IFNGR1 | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 368/908 reads (41%) | catalogued as CD004710, CM154941; called by muse, mutect2, varscan2
- IFNGR1 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 100/1012 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378351929; called by muse, mutect2
- IFT172 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 130/416 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as rs1038040281, COSV53134002; called by muse, mutect2, varscan2
- IGDCC3 | c.1991G>T p.R664M | Missense Mutation (SNP) | VAF 338/1086 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100031573; called by muse, varscan2
- IGDCC4 | c.2536+1G>A p.X846_splice | Splice Site (SNP) | VAF 20/446 reads (4%) | catalogued as rs918996775, COSV61535645; called by muse, mutect2
- IGHMBP2 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 178/389 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs200072932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGSF10 | c.6284G>T p.R2095I | Missense Mutation (SNP) | VAF 183/373 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs908711998, COSV56384364; called by muse, mutect2, varscan2
- IGSF3 | c.3560G>A p.S1187N (on ENST00000369486 / NM_001007237.3; = p.S1207N on NM_001542.4) | Missense Mutation (SNP) | VAF 334/853 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59592832; called by muse, mutect2, varscan2
- IGSF5 | c.581G>T p.S194I | Missense Mutation (SNP) | VAF 64/1082 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV101012026; called by muse, mutect2
- IGSF9 | c.3230+1G>A p.X1077_splice (on ENST00000368094 / NM_001135050.2; = p.X1061_splice on NM_020789.4) | Splice Site (SNP) | VAF 108/311 reads (35%) | catalogued as rs1442382065; called by muse, mutect2, varscan2
- IHH | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 323/806 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.703); catalogued as rs145192358, COSV99838784; called by muse, mutect2, varscan2
- IL17A | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 46/692 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1163865638; called by muse, mutect2
- IL17B | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 334/749 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373011468; called by muse, mutect2, varscan2
- IL17RD | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 157/394 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV56339372; called by muse, mutect2, varscan2
- IL17RE | c.1333C>A p.L445I | Missense Mutation (SNP) | VAF 291/742 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as COSV55967725; called by muse, mutect2, varscan2
- IL26 | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 281/735 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1353873516; called by muse, varscan2
- IL27 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 57/1166 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1219657337; called by muse, mutect2
- IL31RA | c.1943T>C p.L648P | Missense Mutation (SNP) | VAF 94/928 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1045539821, COSV61696849; called by muse, mutect2, varscan2
- IMMP2L | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 353/848 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100069502; called by muse, varscan2
- IMPA1 | c.303-2dup p.X101_splice | Splice Site (INS) | VAF 124/304 reads (41%) | catalogued as rs763126450; called by mutect2, varscan2
- IMPACT | c.490+1G>A p.X164_splice | Splice Site (SNP) | VAF 126/341 reads (37%) | catalogued as rs747954357; called by muse, mutect2, varscan2
- INHBC | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 156/356 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as COSV100548063; called by muse, varscan2
- INO80 | c.2251G>A p.V751M | Missense Mutation (SNP) | VAF 193/480 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756213905; called by muse, mutect2, varscan2
- INPP5D | c.1441G>A p.A481T (on ENST00000445964 / NM_001017915.3; = p.A480T on NM_005541.5) | Missense Mutation (SNP) | VAF 146/366 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs992734549, COSV64038866; called by muse, varscan2
- INPP5F | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 354/908 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1209801558; called by muse, mutect2, varscan2
- INTS1 | c.4531C>T p.R1511C | Missense Mutation (SNP) | VAF 405/934 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs560840118, COSV104431339; called by muse, mutect2, varscan2
- INTS7 | c.1746T>A p.N582K | Missense Mutation (SNP) | VAF 336/780 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV65345203; called by muse, varscan2
- IQCH | c.885G>T p.W295C | Missense Mutation (SNP) | VAF 198/459 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100246227; called by muse, mutect2, varscan2
- IRAG1 | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 232/530 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs751647877; called by muse, mutect2, varscan2
- IRX5 | c.291G>T p.L97F | Missense Mutation (SNP) | VAF 412/994 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV58059864; called by muse, mutect2, varscan2
- ISYNA1 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 272/669 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54210648; called by muse, mutect2, varscan2
- ITGA8 | c.2165G>T p.R722M | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65235419; called by muse, mutect2, varscan2
- ITIH2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 329/893 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV100623324; called by muse, mutect2, varscan2
- ITPR1 | c.2350C>T p.R784C (on ENST00000354582; = p.R769C on NM_002222.7) | Missense Mutation (SNP) | VAF 350/851 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs773602565, COSV56970374; called by muse, mutect2, varscan2
- ITPR3 | c.6901G>A p.V2301M | Missense Mutation (SNP) | VAF 239/667 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as rs768511923; called by muse, mutect2, varscan2
- ITPR3 | c.7198G>A p.D2400N | Missense Mutation (SNP) | VAF 465/1105 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs149593819; called by muse, mutect2, varscan2
- ITPR3 | c.7786-4T>C | Splice Region (SNP) | VAF 325/846 reads (38%) | catalogued as rs1450748139; called by muse, mutect2, varscan2
- ITSN1 | c.3713G>A p.R1238Q | Missense Mutation (SNP) | VAF 538/1320 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201178787, COSV101181849; called by muse, mutect2, varscan2
- JAKMIP3 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 410/961 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV53821943; called by muse, mutect2, varscan2
- JCAD | c.3485A>T p.D1162V | Missense Mutation (SNP) | VAF 164/389 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs761164834; called by muse, mutect2, varscan2
- JMJD1C | c.6962-1G>T p.X2321_splice | Splice Site (SNP) | VAF 145/412 reads (35%) | catalogued as COSV59513330; called by muse, mutect2
- JPH4 | c.512del p.P171Rfs*78 | Frame Shift Del (DEL) | VAF 60/304 reads (20%) | catalogued as rs1255023439; called by mutect2, varscan2
- JUNB | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 287/671 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV56877822; called by muse, mutect2, varscan2
- KANK4 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 208/712 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs964949376, COSV62987757; called by muse, varscan2
- KANSL1 | c.3236C>T p.P1079L (on ENST00000574590 / NM_001193465.2; = p.P1080L on NM_015443.4) | Missense Mutation (SNP) | VAF 329/740 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.034); catalogued as rs768634007; called by muse, mutect2, varscan2
- KCNA2 | c.1410G>T p.E470D | Missense Mutation (SNP) | VAF 223/509 reads (44%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.005); catalogued as COSV60370028; called by muse, mutect2, varscan2
- KCNA3 | c.1539G>T p.E513D | Missense Mutation (SNP) | VAF 234/568 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV63901694; called by muse, varscan2
- KCNA3 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 238/516 reads (46%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs1429139663; called by muse, mutect2, varscan2
- KCNH5 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 446/1072 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1274890582, COSV59760000; called by muse, mutect2, varscan2
- KCNJ1 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 63/551 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs759992526, CM081676, COSV60662829; called by muse, mutect2, varscan2
- KCNJ12 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 537/1316 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782311972, COSV100054434; called by muse, mutect2, varscan2
- KCNJ15 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 351/788 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1383475103; called by muse, mutect2, varscan2
- KCNJ6 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 157/354 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55719951; called by muse, mutect2, varscan2
- KCNK18 | c.290G>T p.R97M | Missense Mutation (SNP) | VAF 447/1049 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.67); catalogued as COSV57972392; called by muse, mutect2, varscan2
- KCNK9 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 230/636 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs753520581; called by muse, mutect2, varscan2
- KCNMA1 | c.1327C>A p.L443I | Missense Mutation (SNP) | VAF 364/883 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as COSV54232640; called by muse, mutect2, varscan2
- KCNN1 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 303/731 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55840657; called by muse, mutect2, varscan2
- KCNS1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 248/508 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1285420387, COSV60260192; called by muse, mutect2, varscan2
- KCNT2 | c.3088G>A p.G1030S | Missense Mutation (SNP) | VAF 106/1756 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs748909802; called by muse, mutect2
- KCP | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 344/788 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs558582103; called by muse, mutect2, varscan2
- KCTD7 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 48/995 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.754); catalogued as COSV99299001; called by muse, mutect2
- KDM3B | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 271/637 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.114); catalogued as rs1356205786; called by muse, varscan2
- KDM8 | c.547dup p.T183Nfs*31 | Frame Shift Ins (INS) | VAF 406/932 reads (44%) | catalogued as rs1180539078; called by mutect2, varscan2
- KHDRBS2 | c.124A>G p.K42E | Missense Mutation (SNP) | VAF 274/783 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV55498840; called by muse, varscan2
- KHDRBS3 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 292/715 reads (41%) | catalogued as rs1173128434, COSV63424392; called by muse, mutect2, varscan2
- KHDRBS3 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 505/1246 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV63415359; called by muse, mutect2, varscan2
- KHNYN | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 131/453 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1010001277; called by muse, mutect2, varscan2
- KIAA0319 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 370/992 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs544402125; called by muse, mutect2, varscan2
- KIAA2013 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 118/326 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100927167; called by muse, mutect2, varscan2
- KIDINS220 | c.2840C>A p.S947Y | Missense Mutation (SNP) | VAF 259/657 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.794); catalogued as COSV56758656; called by muse, mutect2, varscan2
- KIF13B | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 361/829 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs766406923, COSV72954322; called by muse, mutect2, varscan2
- KIF17 | c.1943C>A p.P648H | Missense Mutation (SNP) | VAF 190/528 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.241); catalogued as COSV56122528; called by muse, mutect2, varscan2
- KIF17 | c.1732G>T p.D578Y | Missense Mutation (SNP) | VAF 343/855 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as COSV56117418; called by muse, mutect2, varscan2
- KIF26B | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 44/881 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.841); catalogued as rs758686161; called by muse, mutect2
- KIF26B | c.5708G>A p.R1903Q | Missense Mutation (SNP) | VAF 233/448 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764776788; called by muse, mutect2, varscan2
- KIF3C | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 484/1159 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1216014916, COSV99267298; called by muse, mutect2, varscan2
- KIF5C | c.2785G>A p.G929R | Missense Mutation (SNP) | VAF 348/818 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs372092875; called by muse, mutect2, varscan2
- KIFC3 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 401/918 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as COSV65551379; called by muse, mutect2, varscan2
- KIT | c.2334G>T p.K778N | Missense Mutation (SNP) | VAF 522/1307 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55407727; called by muse, mutect2, varscan2
- KLF11 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 303/719 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558351564; called by muse, mutect2, varscan2
- KLF12 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 88/761 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV66574142; called by muse, mutect2, varscan2
- KLHDC10 | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 242/584 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV59054273; called by muse, mutect2, varscan2
- KLHL1 | c.104dup p.G36Rfs*12 | Frame Shift Ins (INS) | VAF 336/785 reads (43%) | catalogued as rs749011008; called by mutect2, varscan2
- KLHL2 | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 368/972 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243612582; called by muse, mutect2, varscan2
- KLHL38 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 187/378 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as rs370062375; called by muse, mutect2, varscan2
8,477 further variants in this file (4,742 protein-altering or splice-affecting, 1,820 silent, 1,915 other) are not listed here.
